Somatic mutation profile of tumor specimen C3N-00513-03 (aliquot CPT0077790007) from CPTAC case C3N-00513, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.3 years (23,121 days).
Specimen C3N-00513-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5efea77d-d075-436a-94f4-868eb7fca053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00513-31 (Blood Derived Normal), aliquot CPT0077850001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/536c20ef-5ec7-4e16-9859-3c91245329ae

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/316 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ANKRD11 | c.1900A>G p.T634A | Missense Mutation (SNP) | VAF 28/475 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); catalogued as COSV56361714; called by muse, mutect2
- ELOVL3 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- PTCHD3 | c.1847G>T p.S616I | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HOXA4 | c.-9C>A | 5'UTR (SNP) | VAF 17/483 reads (4%) | called by muse, mutect2
